Somatic mutation profile of tumor specimen MP2PRT-PAVEHA-TMP1-A (aliquot MP2PRT-PAVEHA-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVEHA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,337 days).
Specimen MP2PRT-PAVEHA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2287dceb-88db-4de9-a9f3-937c8b354a41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVEHA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVEHA-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a902d4fb-1ca9-42c8-9c8d-a9f8bb63fcc6

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Ins 2, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANCC | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 135/316 reads (43%) | catalogued as rs776529713, COSV56665715; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPRED1 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 68/354 reads (19%) | catalogued as rs1057518683, CM074576; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCSK1N | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 173/598 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as rs376988691; called by muse, mutect2, varscan2
- PRKACG | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55254573; called by muse, varscan2
- SCARA5 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 129/298 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1022398722; called by muse, mutect2, varscan2
- SFTPA1 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 167/447 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368889920; called by muse, mutect2, varscan2
- CNOT1 | c.5328dup p.A1777Cfs*5 | Frame Shift Ins (INS) | VAF 217/620 reads (35%) | called by mutect2, pindel, varscan2
- PIGX | c.653T>A p.L218Q | Missense Mutation (SNP) | VAF 114/232 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RHOBTB2 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 192/455 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC11A1 | c.1190_1191insGCAACCC p.F398Qfs*34 | Frame Shift Ins (INS) | VAF 201/487 reads (41%) | called by mutect2, pindel, varscan2
- STRA8 | c.419G>A p.S140N (on ENST00000275764; = p.S118N on NM_182489.2) | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- HERC6 | c.630C>T p.A210= | Silent (SNP) | VAF 139/334 reads (42%) | catalogued as rs777038107; called by muse, mutect2, varscan2
- SCART1 | c.228C>T p.G76= | Silent (SNP) | VAF 340/712 reads (48%) | catalogued as rs890608398; called by muse, mutect2, varscan2
- TMC6 | c.27C>T p.L9= | Silent (SNP) | VAF 239/790 reads (30%) | catalogued as rs145198906, COSV100130217; called by muse, mutect2, varscan2
- SYTL2 | c.1459+260G>T | Intron (SNP) | VAF 138/314 reads (44%) | catalogued as rs745865319; called by muse, mutect2, varscan2
